Somatic mutation profile of tumor specimen C3N-04142-03 (aliquot CPT0259180006) from CPTAC case C3N-04142, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 81.1 years (29,614 days).
Specimen C3N-04142-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Trunk; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 129b2cda-6a0b-4976-8bf4-df9d4bdf8dfe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-04142-71 (Blood Derived Normal), aliquot CPT0259280002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6523482e-3a53-4022-ad64-f9e2491d9a80

The open-access MAF lists 404 somatic variants for this specimen: 255 protein-altering or splice-affecting, 131 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 236, Silent 131, Intron 11, Nonsense Mutation 10, Splice Region 4, Frame Shift Ins 3, 5'Flank 2, Frame Shift Del 2, 3'Flank 2, 3'UTR 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 148/373 reads (40%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- PAK5 | c.519G>A p.M173I | Missense Mutation (SNP) | VAF 75/398 reads (19%) | hotspot (GDC flag); SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs769939031, COSV62021293; called by muse, mutect2, varscan2
- ACIN1 | c.3019C>T p.R1007W | Missense Mutation (SNP) | VAF 127/366 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs372945260; called by muse, mutect2, varscan2
- ADGRG4 | c.6704C>T p.S2235L | Missense Mutation (SNP) | VAF 53/299 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as rs749693269, COSV54950917; called by muse, mutect2, varscan2
- ADGRV1 | c.12949C>T p.P4317S | Missense Mutation (SNP) | VAF 61/399 reads (15%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.903); catalogued as rs1389413861; called by muse, mutect2, varscan2
- AGBL1 | c.1690C>T p.R564W | Missense Mutation (SNP) | VAF 118/376 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs577916222, COSV101224207; called by muse, mutect2, varscan2
- AK5 | c.754G>A p.E252K (on ENST00000354567 / NM_174858.3; = p.E226K on NM_012093.4) | Missense Mutation (SNP) | VAF 131/382 reads (34%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.963); catalogued as rs1250918521, COSV60967421; called by muse, mutect2, varscan2
- ALB | c.535C>T p.L179F | Missense Mutation (SNP) | VAF 62/390 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.835); catalogued as COSV55738013; called by muse, mutect2, varscan2
- ALOX15 | c.1319C>T p.S440F | Missense Mutation (SNP) | VAF 78/373 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779781592; called by muse, mutect2, varscan2
- ANK3 | c.6332C>T p.S2111F | Missense Mutation (SNP) | VAF 58/286 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.731); catalogued as COSV99779717; called by muse, mutect2, varscan2
- ARHGAP30 | c.1946G>A p.G649E | Missense Mutation (SNP) | VAF 80/479 reads (17%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs779570770; called by muse, mutect2, varscan2
- ASIC5 | c.803G>A p.G268E | Missense Mutation (SNP) | VAF 117/509 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.246); catalogued as rs147908426; called by muse, mutect2, varscan2
- ASPN | c.370G>A p.G124R | Missense Mutation (SNP) | VAF 74/222 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65016058; called by muse, mutect2, varscan2
- ATRNL1 | c.328C>T p.P110S | Missense Mutation (SNP) | VAF 17/144 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs782373907; called by muse, mutect2, varscan2
- BAZ2A | c.341C>T p.S114F | Missense Mutation (SNP) | VAF 173/491 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV51632868; called by muse, mutect2, varscan2
- BCAT1 | c.675G>A p.G225= | Splice Region (SNP) | VAF 69/261 reads (26%) | catalogued as COSV53910615; called by muse, mutect2, varscan2
- BRINP3 | c.1558C>A p.R520S | Missense Mutation (SNP) | VAF 123/375 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV66532324, COSV66543305; called by muse, mutect2, varscan2
- CABP4 | c.113C>G p.T38S | Missense Mutation (SNP) | VAF 85/415 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.018); catalogued as COSV100351637; called by muse, mutect2, varscan2
- CECR2 | c.4370C>T p.S1457L (on ENST00000342247 / NM_001290047.2; = p.S1273L on NM_001290046.1) | Missense Mutation (SNP) | VAF 157/446 reads (35%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.003); catalogued as rs536749791, COSV52850513; called by muse, mutect2, varscan2
- CELSR2 | c.1042G>A p.V348M | Missense Mutation (SNP) | VAF 95/474 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99604761; called by muse, mutect2, varscan2
- CFAP251 | c.2522C>T p.S841F | Missense Mutation (SNP) | VAF 134/389 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.391); catalogued as rs1462461418, COSV99995745; called by muse, mutect2, varscan2
- CFHR4 | c.283G>A p.E95K (on ENST00000367416 / NM_001201551.2; = p.E96K on NM_001201550.3) | Missense Mutation (SNP) | VAF 44/146 reads (30%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.715); catalogued as rs770331706, COSV99261264; called by muse, mutect2, varscan2
- CHPF2 | c.1967G>T p.R656L | Missense Mutation (SNP) | VAF 76/456 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.496); catalogued as rs559445545; called by muse, mutect2, varscan2
- CKB | c.614C>T p.S205L | Missense Mutation (SNP) | VAF 86/497 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.313); catalogued as COSV62379603; called by muse, mutect2, varscan2
- CLSTN3 | c.1405G>A p.D469N | Missense Mutation (SNP) | VAF 186/499 reads (37%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.966); catalogued as rs140338155; called by muse, mutect2, varscan2
- COL19A1 | c.1285C>T p.P429S | Missense Mutation (SNP) | VAF 46/206 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.047); catalogued as rs777127088; called by muse, mutect2, varscan2
- CSMD3 | c.6496G>A p.E2166K (on ENST00000297405 / NM_001363185.1; = p.E2062K on NM_052900.3) | Missense Mutation (SNP) | VAF 71/551 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV52111116; called by muse, mutect2, varscan2
- CTNNB1 | c.1817C>T p.P606L | Missense Mutation (SNP) | VAF 36/295 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.408); catalogued as rs1306221365, COSV62694840; called by muse, mutect2, varscan2
- CYP3A7 | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 58/301 reads (19%) | SIFT tolerated (0.86); PolyPhen benign (0.112); catalogued as rs1343095905; called by muse, mutect2, varscan2
- CYP4F2 | c.492G>A p.M164I | Missense Mutation (SNP) | VAF 81/213 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as COSV99171068; called by muse, mutect2, varscan2
- DDX31 | c.212G>A p.G71E | Missense Mutation (SNP) | VAF 112/672 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as rs867691694; called by muse, mutect2, varscan2
- DHODH | c.25C>T p.R9W | Missense Mutation (SNP) | VAF 40/213 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.794); catalogued as rs1008004964; called by muse, mutect2, varscan2
- DLGAP2 | c.2587C>T p.P863S | Missense Mutation (SNP) | VAF 109/575 reads (19%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.997); catalogued as COSV70098363; called by muse, mutect2, varscan2
- DMD | c.8536G>A p.D2846N | Missense Mutation (SNP) | VAF 61/284 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.091); catalogued as rs753351870, COSV58951715; called by muse, mutect2, varscan2
- DOCK5 | c.4400C>T p.P1467L | Missense Mutation (SNP) | VAF 68/309 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs772062014; called by muse, mutect2, varscan2
- EPHA7 | c.883C>T p.R295C | Missense Mutation (SNP) | VAF 71/342 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.602); catalogued as rs375147203; called by muse, mutect2, varscan2
- EPHB3 | c.986C>T p.S329L | Missense Mutation (SNP) | VAF 142/485 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs747895201; called by muse, mutect2, varscan2
- ERVMER34-1 | c.1655G>A p.G552E | Missense Mutation (SNP) | VAF 50/298 reads (17%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.001); catalogued as rs1369719322; called by muse, mutect2, varscan2
- FAAH | c.757G>A p.G253S | Missense Mutation (SNP) | VAF 163/465 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); catalogued as rs372799954; called by muse, mutect2, varscan2
- FAAH | c.758G>A p.G253D | Missense Mutation (SNP) | VAF 162/459 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as rs779763848; called by muse, mutect2, varscan2
- FBLN5 | c.1313G>A p.R438Q | Missense Mutation (SNP) | VAF 76/369 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs772620656, COSV50903020; called by muse, mutect2, varscan2
- FER1L6 | c.4252G>A p.E1418K | Missense Mutation (SNP) | VAF 45/413 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); catalogued as COSV67552578; called by muse, mutect2, varscan2
- FREM1 | c.3535C>T p.P1179S | Missense Mutation (SNP) | VAF 149/321 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1381393162; called by muse, mutect2, varscan2
- GABRG1 | c.685G>A p.D229N | Missense Mutation (SNP) | VAF 145/379 reads (38%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.936); catalogued as COSV54953934, COSV99777743; called by muse, mutect2, varscan2
- GAREM1 | c.1781C>T p.S594F (on ENST00000269209 / NM_001242409.2; = p.S593F on NM_022751.3) | Missense Mutation (SNP) | VAF 102/309 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.483); catalogued as rs137998360; called by muse, mutect2, varscan2
- GHR | c.807A>T p.L269F | Missense Mutation (SNP) | VAF 97/276 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as COSV50130217; called by muse, mutect2, varscan2
- GPR61 | c.1051G>A p.E351K | Missense Mutation (SNP) | VAF 156/418 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV63984594; called by muse, mutect2, varscan2
- GPRC5D | c.803C>T p.S268L | Missense Mutation (SNP) | VAF 155/378 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.089); catalogued as rs1331949968, COSV57432767; called by muse, mutect2, varscan2
- GRB7 | c.374G>A p.R125H | Missense Mutation (SNP) | VAF 77/365 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.188); catalogued as rs200112951; called by muse, mutect2, varscan2
- GRIN3A | c.410G>A p.R137H | Missense Mutation (SNP) | VAF 135/510 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.791); catalogued as COSV62452146; called by muse, mutect2, varscan2
- HERC2 | c.8821G>A p.G2941R | Missense Mutation (SNP) | VAF 63/173 reads (36%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.789); catalogued as rs761019057; called by muse, mutect2, varscan2
- HHLA1 | c.400C>T p.P134S | Missense Mutation (SNP) | VAF 48/384 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV70152819; called by muse, mutect2, varscan2
- HYDIN | c.9832G>A p.G3278R | Missense Mutation (SNP) | VAF 145/371 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs564737189, COSV66886017; called by muse, mutect2, varscan2
- IGHMBP2 | c.643C>T p.P215S | Missense Mutation (SNP) | VAF 64/277 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1364362474; called by muse, mutect2, varscan2
- IL7 | c.41C>T p.P14L | Missense Mutation (SNP) | VAF 53/536 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.406); catalogued as COSV55675561; called by muse, varscan2
- INSC | c.1372G>A p.E458K | Missense Mutation (SNP) | VAF 88/326 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.382); catalogued as COSV65413583; called by muse, mutect2, varscan2
- INTS14 | c.407G>A p.R136Q (on ENST00000313182 / NM_001366360.2; = p.R57Q on NM_001136043.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 138/413 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.097); catalogued as rs766178838; called by muse, mutect2, varscan2
- KALRN | c.1825G>A p.E609K | Missense Mutation (SNP) | VAF 138/423 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53775349; called by muse, mutect2, varscan2
- KANK4 | c.1466C>T p.S489F | Missense Mutation (SNP) | VAF 74/454 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.092); catalogued as COSV62987378, COSV62989676; called by muse, mutect2, varscan2
- KCTD8 | c.1358C>T p.P453L | Missense Mutation (SNP) | VAF 41/295 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63597483; called by muse, mutect2, varscan2
- KRT7 | c.598G>A p.D200N | Missense Mutation (SNP) | VAF 42/268 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV59332914; called by muse, varscan2
- LILRB2 | c.562C>T p.P188S | Missense Mutation (SNP) | VAF 230/603 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.652); catalogued as rs199771422, COSV58743518; called by muse, mutect2, varscan2
- LRRC24 | c.1510C>T p.P504S | Missense Mutation (SNP) | VAF 69/645 reads (11%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.001); catalogued as rs1353309803, COSV99467796; called by muse, mutect2, varscan2
- LYPD6B | c.208G>A p.D70N (on ENST00000409029 / NM_001317004.1; = p.D94N on NM_177964.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 60/362 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs780493473, COSV54518689; called by muse, mutect2, varscan2
- MAGEC1 | c.3202G>A p.E1068K | Missense Mutation (SNP) | VAF 90/374 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.881); catalogued as rs199683263, COSV53573910; called by muse, mutect2, varscan2
- MAMDC2 | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 207/649 reads (32%) | SIFT tolerated (0.85); PolyPhen benign (0.023); catalogued as COSV101015217, COSV65857916; called by muse, mutect2, varscan2
- MAPK8IP3 | c.436C>T p.Q146* | Nonsense Mutation (SNP) | VAF 48/264 reads (18%) | catalogued as COSV51716465; called by muse, mutect2, varscan2
- METAP1D | c.128G>A p.R43Q | Missense Mutation (SNP) | VAF 113/330 reads (34%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs781682409; called by muse, mutect2, varscan2
- METTL9 | c.121G>A p.G41S | Missense Mutation (SNP) | VAF 64/395 reads (16%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as rs780224868; called by muse, mutect2, varscan2
- MGAM | c.2222T>G p.L741R | Missense Mutation (SNP) | VAF 106/283 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV72075243; called by muse, mutect2, varscan2
- MITF | c.316C>T p.P106S | Missense Mutation (SNP) | VAF 120/318 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.917); catalogued as COSV58891761; called by muse, mutect2, varscan2
- MLH1 | c.2209G>A p.D737N | Missense Mutation (SNP) | VAF 142/485 reads (29%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.639); catalogued as rs1559596742; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MRGPRX1 | c.571C>T p.L191F | Missense Mutation (SNP) | VAF 88/410 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as rs1368499311, COSV57107436; called by muse, mutect2, varscan2
- MTNR1A | c.511G>A p.D171N | Missense Mutation (SNP) | VAF 81/477 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); catalogued as COSV56155323; called by muse, mutect2, varscan2
- MYO3B | c.1418C>T p.S473F | Missense Mutation (SNP) | VAF 60/306 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.704); catalogued as rs746744711, COSV58711463; called by muse, mutect2, varscan2
- MYOZ2 | c.662C>T p.S221F | Missense Mutation (SNP) | VAF 95/396 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV61084465; called by muse, mutect2, varscan2
- NBEA | c.5618C>T p.P1873L | Missense Mutation (SNP) | VAF 76/249 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.702); catalogued as rs1321366226; called by muse, mutect2, varscan2
- NHEJ1 | c.563C>T p.S188F | Missense Mutation (SNP) | VAF 39/264 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.743); catalogued as COSV59429224; called by muse, mutect2, varscan2
- NLRC3 | c.194G>A p.R65K | Missense Mutation (SNP) | VAF 70/354 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100073120; called by muse, mutect2, varscan2
- NRK | c.1999G>A p.E667K | Missense Mutation (SNP) | VAF 107/355 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.34); catalogued as COSV54600539, COSV99689148; called by muse, mutect2, varscan2
- OR4K1 | c.460C>T p.L154F | Missense Mutation (SNP) | VAF 55/470 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.111); catalogued as rs1479982265, COSV53460888, COSV53462460; called by muse, mutect2, varscan2
- OR51G1 | c.673C>T p.R225C | Missense Mutation (SNP) | VAF 34/176 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as rs200001303; called by muse, mutect2, varscan2
- OR6Y1 | c.700C>T p.P234S | Missense Mutation (SNP) | VAF 89/402 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.896); catalogued as rs1282071108; called by muse, mutect2, varscan2
- ORM2 | c.133T>C p.Y45H | Missense Mutation (SNP) | VAF 90/369 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs750499471; called by muse, mutect2, varscan2
- P2RY10 | c.427G>A p.D143N | Missense Mutation (SNP) | VAF 99/410 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV99409262; called by muse, mutect2, varscan2
- PARD3 | c.3434G>A p.R1145K | Missense Mutation (SNP) | VAF 41/171 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs767144768; called by muse, mutect2, varscan2
- PARD3B | c.3572G>A p.R1191Q (on ENST00000406610 / NM_001302769.2; = p.R1122Q on NM_057177.7) | Missense Mutation (SNP) | VAF 98/469 reads (21%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.984); catalogued as rs201991047, COSV62519664; called by muse, mutect2, varscan2
- PCDH15 | c.4550C>G p.S1517C | Missense Mutation (SNP) | VAF 59/270 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.928); catalogued as rs759303089; called by muse, mutect2, varscan2
- PCDHB8 | c.931G>A p.E311K | Missense Mutation (SNP) | VAF 52/970 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs148140727, COSV50755144; called by muse, mutect2
- PCDHGA11 | c.1682C>T p.P561L | Missense Mutation (SNP) | VAF 202/530 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1260941191; called by muse, mutect2, varscan2
- PCSK5 | c.2756C>T p.S919L | Missense Mutation (SNP) | VAF 60/380 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs762281568, COSV70449275; called by muse, mutect2, varscan2
- PLXNA4 | c.2719G>A p.G907S | Missense Mutation (SNP) | VAF 75/361 reads (21%) | SIFT tolerated (0.43); PolyPhen benign (0.158); catalogued as rs747435244; called by muse, mutect2, varscan2
- POM121L12 | c.563G>A p.G188E | Missense Mutation (SNP) | VAF 152/496 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs1689291, COSV68692218; called by muse, mutect2, varscan2
- PPP1R1A | c.211C>T p.R71W | Missense Mutation (SNP) | VAF 79/405 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.927); catalogued as rs1220829848, COSV99226304; called by muse, mutect2, varscan2
- PTPRG | c.1691C>T p.P564L | Missense Mutation (SNP) | VAF 173/550 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as rs761095761; called by muse, mutect2, varscan2
- RHOU | c.729G>A p.M243I | Missense Mutation (SNP) | VAF 41/344 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV64208977; called by muse, mutect2, varscan2
- RIC3 | c.634G>A p.E212K (on ENST00000309737 / NM_001206671.4; = p.E211K on NM_024557.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 51/264 reads (19%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); catalogued as COSV58300821; called by muse, mutect2, varscan2
- RIMS1 | c.3431G>A p.R1144Q | Missense Mutation (SNP) | VAF 53/280 reads (19%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.357); catalogued as rs765007580; called by muse, mutect2, varscan2
- S1PR4 | c.997G>A p.G333R | Missense Mutation (SNP) | VAF 178/605 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as rs1457647312; called by muse, mutect2, varscan2
- SALL1 | c.274G>A p.D92N | Missense Mutation (SNP) | VAF 76/425 reads (18%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV51753505, COSV51765954; called by muse, mutect2, varscan2
- SALL4 | c.3002C>T p.S1001F | Missense Mutation (SNP) | VAF 181/512 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.201); catalogued as COSV53854539; called by muse, mutect2, varscan2
- SEMA3G | c.1591G>A p.E531K | Missense Mutation (SNP) | VAF 194/569 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as COSV99203549; called by muse, mutect2, varscan2
- SGCE | c.463A>G p.T155A (on ENST00000647096; = p.T119A on NM_003919.3) | Missense Mutation (SNP) | VAF 14/454 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.054); catalogued as COSV56018076; called by muse, mutect2
- SIPA1L1 | c.833G>A p.R278K | Missense Mutation (SNP) | VAF 131/356 reads (37%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.931); catalogued as rs146015875; called by muse, mutect2, varscan2
- SLAIN1 | c.1019C>T p.P340L (on ENST00000466548; = p.P77L on NM_144595.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 125/458 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.098); catalogued as rs928892558; called by muse, mutect2, varscan2
- SLC22A16 | c.1130C>T p.S377F | Missense Mutation (SNP) | VAF 84/299 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs747426690, COSV100397118; called by muse, mutect2, varscan2
- SLC25A52 | c.262C>T p.R88* (on ENST00000672005; = p.R78* on NM_001034172.4) | Nonsense Mutation (SNP) | VAF 169/467 reads (36%) | catalogued as COSV52502938; called by muse, mutect2, varscan2
- SLC38A10 | c.2828G>A p.G943D | Missense Mutation (SNP) | VAF 107/423 reads (25%) | SIFT tolerated (0.55); PolyPhen benign (0.005); catalogued as COSV66102821; called by muse, mutect2, varscan2
- SPINT1 | c.1021C>T p.R341C (on ENST00000344051 / NM_181642.3; = p.R325C on NM_003710.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 86/262 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs201483554; called by muse, mutect2, varscan2
- SPTLC3 | c.434C>T p.S145L | Missense Mutation (SNP) | VAF 95/280 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as rs928804605, COSV100983231, COSV65466906; called by mutect2, varscan2
- TBX15 | c.605C>T p.S202F (on ENST00000369429 / NM_001330677.2; = p.S96F on NM_152380.3) | Missense Mutation (SNP) | VAF 159/402 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52873157; called by muse, mutect2, varscan2
- TNFRSF10D | c.880G>A p.E294K | Missense Mutation (SNP) | VAF 80/352 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57035171; called by muse, mutect2, varscan2
- TRIM60 | c.1408G>A p.E470K | Missense Mutation (SNP) | VAF 41/210 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV100593916, COSV100593956; called by muse, mutect2, varscan2
- TRIOBP | c.4232_4233del p.R1411Tfs*30 | Frame Shift Del (DEL) | VAF 94/566 reads (17%) | catalogued as rs1233777224; called by pindel, varscan2
- TTN | c.101173G>A p.G33725R (on ENST00000591111; = p.G26301R on NM_003319.4) | Missense Mutation (SNP) | VAF 67/339 reads (20%) | PolyPhen probably damaging (0.992); catalogued as rs1267912817; called by muse, mutect2, varscan2
- UGT2B17 | c.1321G>A p.E441K | Missense Mutation (SNP) | VAF 45/221 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.414); catalogued as rs777980350, COSV58500856, COSV58502756; called by muse, mutect2, varscan2
- WNK3 | c.1466C>T p.T489M | Missense Mutation (SNP) | VAF 72/365 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.608); catalogued as rs373983548, COSV63614592; called by muse, mutect2, varscan2
- WSCD2 | c.430C>T p.R144* | Nonsense Mutation (SNP) | VAF 86/469 reads (18%) | catalogued as COSV54584094; called by muse, mutect2, varscan2
- ZBTB4 | c.562C>T p.P188S | Missense Mutation (SNP) | VAF 75/409 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.019); catalogued as rs17854296, COSV60980966; called by muse, mutect2, varscan2
- ZNF239 | c.1369C>T p.P457S | Missense Mutation (SNP) | VAF 50/200 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.005); catalogued as COSV60019172; called by muse, mutect2, varscan2
- ZNF831 | c.4958G>A p.G1653E | Missense Mutation (SNP) | VAF 61/364 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100926123; called by muse, mutect2, varscan2
- ADAD2 | c.1489G>A p.E497K (on ENST00000315906 / NM_001145400.2; = p.E579K on NM_139174.4) | Missense Mutation (SNP) | VAF 195/537 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADAMTSL1 | c.1576T>C p.F526L | Missense Mutation (SNP) | VAF 90/178 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- ADAMTSL2 | c.625G>A p.D209N | Missense Mutation (SNP) | VAF 115/429 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- AGBL1 | c.859C>T p.P287S | Missense Mutation (SNP) | VAF 71/397 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.331); called by muse, mutect2, varscan2
- ALDH8A1 | c.175C>T p.P59S | Missense Mutation (SNP) | VAF 72/340 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- AMPH | c.1729C>T p.P577S | Missense Mutation (SNP) | VAF 172/487 reads (35%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, varscan2
- ANKLE2 | c.1775C>T p.S592F | Missense Mutation (SNP) | VAF 72/396 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANKRD20A4P | c.694G>A p.G232R | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by mutect2, varscan2
- ANKRD20A4P | c.695G>A p.G232E | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.988); called by mutect2, varscan2
- AP5M1 | c.1261C>T p.P421S | Missense Mutation (SNP) | VAF 60/308 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- ATXN3L | c.289C>T p.P97S | Missense Mutation (SNP) | VAF 62/306 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- BCORL1 | c.1091C>T p.S364F | Missense Mutation (SNP) | VAF 122/524 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- BEND4 | c.527G>A p.S176N | Missense Mutation (SNP) | VAF 111/333 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- BICD2 | c.1295C>T p.P432L | Missense Mutation (SNP) | VAF 156/516 reads (30%) | SIFT tolerated (0.72); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- BICD2 | c.1294C>T p.P432S | Missense Mutation (SNP) | VAF 153/513 reads (30%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- C1QTNF5 | c.317T>G p.F106C | Missense Mutation (SNP) | VAF 95/486 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C2CD4C | c.247C>T p.P83S | Missense Mutation (SNP) | VAF 102/327 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- CD14 | c.983G>A p.G328E | Missense Mutation (SNP) | VAF 171/510 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- CD163L1 | c.1194G>A p.W398* | Nonsense Mutation (SNP) | VAF 133/410 reads (32%) | called by muse, mutect2, varscan2
- CEACAM1 | c.464A>G p.N155S | Missense Mutation (SNP) | VAF 241/461 reads (52%) | SIFT tolerated (0.46); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- CFAP57 | c.2569G>A p.E857K | Missense Mutation (SNP) | VAF 136/408 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- CFAP74 | c.3713C>T p.S1238F | Missense Mutation (SNP) | VAF 60/317 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- CIT | c.4373G>A p.R1458Q | Missense Mutation (SNP) | VAF 38/251 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- CLCA2 | c.2401G>A p.E801K | Missense Mutation (SNP) | VAF 25/134 reads (19%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.8); called by muse, mutect2, varscan2
- CMYA5 | c.6575C>T p.P2192L | Missense Mutation (SNP) | VAF 89/405 reads (22%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- COL12A1 | c.8872G>A p.E2958K | Missense Mutation (SNP) | VAF 111/463 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- COL6A3 | c.3304G>A p.G1102R | Missense Mutation (SNP) | VAF 177/465 reads (38%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CRTAC1 | c.1218G>A p.G406= | Splice Region (SNP) | VAF 52/239 reads (22%) | called by muse, mutect2, varscan2
- CSF3R | c.996G>A p.R332= | Splice Region (SNP) | VAF 68/345 reads (20%) | called by muse, mutect2, varscan2
- CSMD2 | c.5021T>C p.V1674A | Missense Mutation (SNP) | VAF 74/417 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- CSMD2 | c.962G>T p.S321I | Missense Mutation (SNP) | VAF 146/396 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.099); called by muse, varscan2
- CUL3 | c.1132C>T p.L378F | Missense Mutation (SNP) | VAF 59/344 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- CYLD | c.487T>A p.F163I | Missense Mutation (SNP) | VAF 72/203 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DCLK3 | c.1031C>T p.P344L | Missense Mutation (SNP) | VAF 206/702 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DDX31 | c.211G>A p.G71R | Missense Mutation (SNP) | VAF 112/671 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DDX3X | c.1418A>T p.D473V (on ENST00000399959; = p.D474V on NM_001356.5) | Missense Mutation (SNP) | VAF 77/386 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- DHX35 | c.1459C>T p.P487S | Missense Mutation (SNP) | VAF 102/322 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH3 | c.2840C>T p.S947F | Missense Mutation (SNP) | VAF 35/277 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- EIF4B | c.175G>A p.D59N | Missense Mutation (SNP) | VAF 52/268 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.45); called by muse, mutect2, varscan2
- EPHA1 | c.388G>A p.D130N | Missense Mutation (SNP) | VAF 128/399 reads (32%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- EPHB2 | c.868C>T p.P290S | Missense Mutation (SNP) | VAF 175/438 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ERVMER34-1 | c.1654G>A p.G552R | Missense Mutation (SNP) | VAF 50/303 reads (17%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- ETV7 | c.769G>A p.D257N | Missense Mutation (SNP) | VAF 74/312 reads (24%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- EYA2 | c.586C>T p.P196S | Missense Mutation (SNP) | VAF 178/516 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- F2RL2 | c.941T>A p.F314Y | Missense Mutation (SNP) | VAF 166/420 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FIGNL1 | c.685C>T p.H229Y | Missense Mutation (SNP) | VAF 144/377 reads (38%) | SIFT tolerated (0.5); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- FILIP1 | c.2021C>T p.A674V | Missense Mutation (SNP) | VAF 30/220 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- FOXG1 | c.638A>C p.K213T | Missense Mutation (SNP) | VAF 15/427 reads (4%) | SIFT tolerated (0.27); PolyPhen benign (0.345); called by muse, mutect2
- GLG1 | c.2591T>G p.F864C | Missense Mutation (SNP) | VAF 82/411 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GPR179 | c.3104C>T p.S1035F (on ENST00000621958; = p.S1034F on NM_001004334.4) | Missense Mutation (SNP) | VAF 132/565 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GRIK5 | c.173C>T p.P58L | Missense Mutation (SNP) | VAF 190/398 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GRM6 | c.59G>A p.W20* | Nonsense Mutation (SNP) | VAF 157/432 reads (36%) | called by muse, mutect2, varscan2
- HERC1 | c.9331G>A p.E3111K | Missense Mutation (SNP) | VAF 97/459 reads (21%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.453); called by muse, mutect2, varscan2
- HHIPL1 | c.1012G>A p.D338N | Missense Mutation (SNP) | VAF 74/399 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- HK3 | c.932G>A p.G311E | Missense Mutation (SNP) | VAF 74/315 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- HORMAD2 | c.175G>A p.G59R | Missense Mutation (SNP) | VAF 96/264 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- HORMAD2 | c.268T>G p.C90G | Missense Mutation (SNP) | VAF 37/293 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- HTR2B | c.802T>C p.F268L | Missense Mutation (SNP) | VAF 79/430 reads (18%) | SIFT tolerated (0.46); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- INHBA | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 169/513 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- IQSEC2 | c.3910G>A p.G1304S | Missense Mutation (SNP) | VAF 79/313 reads (25%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- ITSN1 | c.4364C>T p.T1455I | Missense Mutation (SNP) | VAF 106/380 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KCNC2 | c.1061G>A p.R354K | Missense Mutation (SNP) | VAF 88/427 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LONRF3 | c.1204G>A p.D402N (on ENST00000371628 / NM_001031855.3; = p.D361N on NM_024778.5) | Missense Mutation (SNP) | VAF 109/496 reads (22%) | SIFT tolerated (0.39); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- LRGUK | c.1357C>T p.P453S | Missense Mutation (SNP) | VAF 119/320 reads (37%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- LY6G5B | c.428C>T p.S143F | Missense Mutation (SNP) | VAF 245/559 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- MAGEB16 | c.943G>A p.E315K | Missense Mutation (SNP) | VAF 64/324 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- MAP7D2 | c.140G>A p.G47E | Missense Mutation (SNP) | VAF 55/268 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- MCM10 | c.317C>T p.P106L | Missense Mutation (SNP) | VAF 44/265 reads (17%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MEGF10 | c.1663G>A p.G555S | Missense Mutation (SNP) | VAF 105/315 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MORN4 | c.124C>T p.H42Y | Missense Mutation (SNP) | VAF 79/340 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- MTIF3 | c.461G>A p.G154E | Missense Mutation (SNP) | VAF 81/278 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- MUC16 | c.26189C>T p.S8730F | Missense Mutation (SNP) | VAF 84/433 reads (19%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- MYO7A | c.5657C>T p.P1886L | Missense Mutation (SNP) | VAF 40/240 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- MYT1 | c.329G>A p.G110E | Missense Mutation (SNP) | VAF 131/366 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NEBL | c.1852C>T p.Q618* | Nonsense Mutation (SNP) | VAF 61/240 reads (25%) | called by muse, mutect2, varscan2
- NETO1 | c.810G>A p.W270* | Nonsense Mutation (SNP) | VAF 71/365 reads (19%) | called by muse, mutect2, varscan2
- NETO1 | c.809G>A p.W270* | Nonsense Mutation (SNP) | VAF 71/366 reads (19%) | called by muse, mutect2, varscan2
- NGEF | c.830C>T p.A277V | Missense Mutation (SNP) | VAF 50/228 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- NHSL1 | c.2745_2746insC p.E916Rfs*76 | Frame Shift Ins (INS) | VAF 75/366 reads (20%) | called by mutect2, varscan2*
- NHSL1 | c.2743del p.T915Lfs*7 | Frame Shift Del (DEL) | VAF 74/374 reads (20%) | called by muse*, mutect2, varscan2*
- NNT | c.443C>T p.S148L | Missense Mutation (SNP) | VAF 74/342 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- NOX1 | c.1689T>A p.N563K | Missense Mutation (SNP) | VAF 25/183 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- NRG3 | c.1297G>A p.E433K | Missense Mutation (SNP) | VAF 35/190 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- NSF | c.1931G>A p.G644E | Missense Mutation (SNP) | VAF 56/267 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- OR4L1 | c.438A>G p.I146M | Missense Mutation (SNP) | VAF 76/394 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.015); called by muse, varscan2
- OR51V1 | c.862C>T p.P288S | Missense Mutation (SNP) | VAF 52/249 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR6N1 | c.853C>T p.L285F | Missense Mutation (SNP) | VAF 64/381 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PADI3 | c.11dup p.R5Efs*31 | Frame Shift Ins (INS) | VAF 123/410 reads (30%) | called by mutect2, pindel, varscan2
- PDZD2 | c.638G>A p.G213E | Missense Mutation (SNP) | VAF 103/483 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- PELP1 | c.1705C>T p.P569S | Missense Mutation (SNP) | VAF 101/382 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- PHF20L1 | c.94C>T p.R32* | Nonsense Mutation (SNP) | VAF 56/482 reads (12%) | called by muse, mutect2, varscan2
- PIDD1 | c.1036C>T p.P346S | Missense Mutation (SNP) | VAF 88/415 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PIEZO2 | c.2632G>A p.D878N | Missense Mutation (SNP) | VAF 75/452 reads (17%) | SIFT tolerated (0.43); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- PKD1L1 | c.874C>T p.P292S | Missense Mutation (SNP) | VAF 74/441 reads (17%) | SIFT tolerated (0.63); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- PLAAT4 | c.131G>A p.G44E | Missense Mutation (SNP) | VAF 50/237 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- PLG | c.2152G>A p.E718K | Missense Mutation (SNP) | VAF 46/198 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- PMF1-BGLAP | c.596C>T p.P199L | Missense Mutation (SNP) | VAF 123/340 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.294); called by muse, mutect2, varscan2
- PNN | c.2048C>T p.S683F | Missense Mutation (SNP) | VAF 68/324 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- POLA1 | c.286G>A p.D96N | Missense Mutation (SNP) | VAF 79/398 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- POLQ | c.2699C>T p.P900L | Missense Mutation (SNP) | VAF 155/513 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- POTEG | c.457C>T p.P153S | Missense Mutation (SNP) | VAF 42/1013 reads (4%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.825); called by muse, mutect2
- PRDM16 | c.2543C>T p.P848L | Missense Mutation (SNP) | VAF 209/645 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.212); called by muse, mutect2
- PRSS23 | c.427G>A p.D143N | Missense Mutation (SNP) | VAF 76/361 reads (21%) | SIFT tolerated (0.76); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- PSG5 | c.331A>G p.N111D | Missense Mutation (SNP) | VAF 177/327 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- PUM1 | c.922G>A p.E308K | Missense Mutation (SNP) | VAF 129/347 reads (37%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- RAB9B | c.170C>T p.T57I | Missense Mutation (SNP) | VAF 64/306 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- RAD54L2 | c.3701C>T p.S1234F | Missense Mutation (SNP) | VAF 193/591 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- RMDN3 | c.1081G>A p.E361K | Missense Mutation (SNP) | VAF 83/353 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- RSPH10B2 | c.719G>A p.G240E | Missense Mutation (SNP) | VAF 48/213 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RUNDC3B | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 96/287 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SAYSD1 | c.458C>T p.S153F | Missense Mutation (SNP) | VAF 72/309 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SEMA4F | c.2116C>T p.P706S | Missense Mutation (SNP) | VAF 167/438 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- SGPP1 | c.772C>T p.L258= | Splice Region (SNP) | VAF 93/245 reads (38%) | called by muse, mutect2, varscan2
- SLAIN1 | c.1018C>T p.P340S (on ENST00000466548; = p.P77S on NM_144595.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 123/463 reads (27%) | SIFT tolerated (0.7); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SLC9A4 | c.2200G>A p.E734K | Missense Mutation (SNP) | VAF 60/397 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLCO1C1 | c.561G>A p.W187* | Nonsense Mutation (SNP) | VAF 160/405 reads (40%) | called by muse, mutect2, varscan2
- SMAD5 | c.337C>T p.P113S | Missense Mutation (SNP) | VAF 142/379 reads (37%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.672); called by muse, mutect2, varscan2
- SP140 | c.1649G>A p.R550K | Missense Mutation (SNP) | VAF 116/302 reads (38%) | SIFT tolerated (0.38); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- SRC | c.752C>T p.S251F | Missense Mutation (SNP) | VAF 210/576 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- TCIRG1 | c.974C>T p.S325F | Missense Mutation (SNP) | VAF 86/439 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- TLR5 | c.2414C>T p.S805F | Missense Mutation (SNP) | VAF 161/432 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.452); called by muse, varscan2
- TMEM108 | c.1579G>A p.E527K | Missense Mutation (SNP) | VAF 84/372 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- TMEM151B | c.1150G>A p.V384M | Missense Mutation (SNP) | VAF 94/460 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- TMPRSS15 | c.1237C>T p.P413S | Missense Mutation (SNP) | VAF 132/460 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- TNRC6A | c.5197C>T p.P1733S | Missense Mutation (SNP) | VAF 182/477 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TRMU | c.179T>C p.V60A | Missense Mutation (SNP) | VAF 156/403 reads (39%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- TRPM2 | c.227T>C p.V76A | Missense Mutation (SNP) | VAF 135/510 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.633); called by muse, mutect2, varscan2
- TTN | c.75968dup p.N25323Kfs*20 (on ENST00000591111; = p.N17899Kfs*20 on NM_003319.4) | Frame Shift Ins (INS) | VAF 140/451 reads (31%) | called by mutect2, pindel, varscan2
- WDFY3 | c.1624C>A p.Q542K | Missense Mutation (SNP) | VAF 11/297 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.153); called by muse, mutect2
- WDR72 | c.592G>A p.E198K | Missense Mutation (SNP) | VAF 84/237 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- ZNF208 | c.2647C>T p.H883Y | Missense Mutation (SNP) | VAF 111/324 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- ZNF516 | c.238C>T p.H80Y | Missense Mutation (SNP) | VAF 137/444 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF684 | c.854C>T p.S285F | Missense Mutation (SNP) | VAF 147/364 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- ZNF714 | c.610G>A p.E204K | Missense Mutation (SNP) | VAF 35/277 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.058); called by muse, varscan2
- ACIN1 | c.3018C>T p.P1006= | Silent (SNP) | VAF 129/370 reads (35%) | called by muse, mutect2, varscan2
- ADAM30 | c.168G>A p.Q56= | Silent (SNP) | VAF 121/353 reads (34%) | called by muse, mutect2, varscan2
- ADAMTS4 | c.180G>A p.E60= | Silent (SNP) | VAF 144/439 reads (33%) | catalogued as rs945190981; called by muse, mutect2, varscan2
- ADGRB3 | c.1251G>A p.S417= | Silent (SNP) | VAF 69/313 reads (22%) | catalogued as rs1172160699, COSV65390770; called by muse, mutect2, varscan2
- AGPAT2 | c.354C>T p.I118= | Silent (SNP) | VAF 136/421 reads (32%) | catalogued as rs762530411, COSV58247901; called by muse, mutect2, varscan2
- ANO4 | c.2349C>T p.I783= (on ENST00000392977 / NM_001286615.2; = p.I748= on NM_178826.4) | Silent (SNP) | VAF 50/300 reads (17%) | catalogued as COSV54584537; called by muse, mutect2, varscan2
- ARSF | c.1005G>A p.R335= | Silent (SNP) | VAF 64/320 reads (20%) | catalogued as COSV63839681; called by muse, mutect2, varscan2
- ASZ1 | c.540G>A p.E180= | Silent (SNP) | VAF 100/290 reads (34%) | catalogued as COSV52915790; called by muse, mutect2, varscan2
- ATP7B | c.2319C>T p.F773= | Silent (SNP) | VAF 96/313 reads (31%) | called by muse, mutect2, varscan2
- AVPR2 | c.534C>T p.F178= | Silent (SNP) | VAF 132/581 reads (23%) | catalogued as rs782190462; called by muse, mutect2, varscan2
- BDKRB1 | c.1041C>T p.F347= | Silent (SNP) | VAF 65/194 reads (34%) | called by muse, mutect2, varscan2
- BRINP1 | c.729C>T p.V243= | Silent (SNP) | VAF 137/408 reads (34%) | called by muse, mutect2, varscan2
- C12orf40 | c.567C>T p.D189= | Silent (SNP) | VAF 27/212 reads (13%) | catalogued as rs375926680; called by muse, mutect2, varscan2
- C4orf50 | c.321C>T p.L107= | Silent (SNP) | VAF 115/343 reads (34%) | called by muse, mutect2, varscan2
- C6 | c.1428G>A p.V476= | Silent (SNP) | VAF 53/209 reads (25%) | called by muse, mutect2, varscan2
- CALR | c.339T>C p.F113= | Silent (SNP) | VAF 126/331 reads (38%) | called by muse, mutect2, varscan2
- CBY2 | c.444C>T p.S148= | Silent (SNP) | VAF 90/418 reads (22%) | called by muse, mutect2, varscan2
- CCDC141 | c.2877G>A p.R959= | Silent (SNP) | VAF 23/178 reads (13%) | catalogued as COSV55369493; called by muse, mutect2, varscan2
- CDH20 | c.201C>T p.F67= | Silent (SNP) | VAF 105/323 reads (33%) | catalogued as rs745478230, COSV53005073, COSV53013848; called by muse, mutect2, varscan2
- CDR2L | c.870C>T p.P290= | Silent (SNP) | VAF 86/410 reads (21%) | called by muse, mutect2, varscan2
- COL4A2 | c.2856C>T p.F952= | Silent (SNP) | VAF 135/481 reads (28%) | catalogued as rs747574881, COSV64625998; ClinVar: likely benign; called by muse, mutect2, varscan2
- CSPG4 | c.2275C>T p.L759= | Silent (SNP) | VAF 87/531 reads (16%) | called by muse, mutect2, varscan2
- CWH43 | c.939G>A p.G313= | Silent (SNP) | VAF 96/391 reads (25%) | catalogued as rs142482409; called by muse, mutect2, varscan2
- CYLC1 | c.1614C>T p.I538= | Silent (SNP) | VAF 58/368 reads (16%) | catalogued as COSV100254211, COSV61411303; called by muse, mutect2, varscan2
- CYP2B6 | c.114C>T p.P38= | Silent (SNP) | VAF 297/509 reads (58%) | called by muse, mutect2, varscan2
- DEFB112 | c.231C>T p.I77= | Silent (SNP) | VAF 61/278 reads (22%) | catalogued as COSV59182324; called by muse, mutect2, varscan2
- DHX15 | c.2241C>T p.I747= | Silent (SNP) | VAF 97/282 reads (34%) | called by muse, mutect2, varscan2
- DNAAF2 | c.1146C>T p.S382= | Silent (SNP) | VAF 118/496 reads (24%) | called by muse, mutect2, varscan2
- DNAH10 | c.4878C>T p.F1626= (on ENST00000409039; = p.F1565= on NM_207437.3) | Silent (SNP) | VAF 106/462 reads (23%) | catalogued as rs773000743, COSV68987681; called by muse, mutect2, varscan2
- DNAH12 | c.3013T>C p.L1005= (on ENST00000351747; = p.L1028= on NM_001366028.2) | Silent (SNP) | VAF 130/326 reads (40%) | catalogued as rs1477200918; called by muse, mutect2, varscan2
- EML5 | c.2583G>A p.G861= | Silent (SNP) | VAF 64/408 reads (16%) | called by muse, mutect2, varscan2
- FAT3 | c.6078C>T p.F2026= | Silent (SNP) | VAF 58/260 reads (22%) | called by muse, mutect2, varscan2
- FREM1 | c.4926G>A p.L1642= | Silent (SNP) | VAF 81/340 reads (24%) | catalogued as rs768887075; called by muse, mutect2, varscan2
- FZD5 | c.1710G>A p.P570= | Silent (SNP) | VAF 69/394 reads (18%) | catalogued as rs780323223, COSV54943068; called by muse, mutect2, varscan2
- GALNT9 | c.465G>A p.V155= | Silent (SNP) | VAF 152/388 reads (39%) | called by muse, mutect2, varscan2
- GPR39 | c.117C>T p.I39= | Silent (SNP) | VAF 165/411 reads (40%) | catalogued as COSV61425213; called by muse, mutect2, varscan2
- GRIA2 | c.1359C>T p.I453= | Silent (SNP) | VAF 65/366 reads (18%) | catalogued as rs752578545, COSV52383835; called by muse, mutect2, varscan2
- GSDMC | c.612G>A p.A204= | Silent (SNP) | VAF 70/678 reads (10%) | catalogued as rs371164178; called by muse, mutect2, varscan2
- HHIPL1 | c.369G>A p.R123= | Silent (SNP) | VAF 175/453 reads (39%) | catalogued as rs1409833184; called by muse, mutect2, varscan2
- HMSD | c.261G>A p.T87= | Silent (SNP) | VAF 53/242 reads (22%) | catalogued as rs1384875525, COSV101282944, COSV68816978; called by muse, mutect2, varscan2
- IFNA7 | c.240C>T p.L80= | Silent (SNP) | VAF 107/321 reads (33%) | called by mutect2, varscan2
- IGFN1 | c.1818G>A p.T606= (on ENST00000295591 / NM_001367841.1; = p.T3063= on NM_001164586.2) | Silent (SNP) | VAF 95/568 reads (17%) | catalogued as rs571379335; called by muse, mutect2, varscan2
- IGHV1-46 | c.144C>T p.F48= | Silent (SNP) | VAF 57/289 reads (20%) | catalogued as rs782006518; called by muse, mutect2, varscan2
- IL4I1 | c.546C>T p.I182= | Silent (SNP) | VAF 47/235 reads (20%) | catalogued as rs1269513019; called by muse, mutect2, varscan2
- IQSEC1 | c.2373C>T p.F791= | Silent (SNP) | VAF 99/337 reads (29%) | catalogued as COSV56221792; called by muse, mutect2, varscan2
- IQUB | c.2349T>A p.I783= | Silent (SNP) | VAF 120/310 reads (39%) | catalogued as COSV100227131; called by muse, mutect2, varscan2
- KIAA0825 | c.3378G>A p.T1126= | Silent (SNP) | VAF 157/396 reads (40%) | catalogued as rs765753863, COSV70250665; called by muse, mutect2, varscan2
- KIR3DL1 | c.840C>T p.F280= | Silent (SNP) | VAF 129/505 reads (26%) | catalogued as rs765913238, COSV58487495; called by muse, mutect2, varscan2
- KLHL25 | c.828C>T p.I276= | Silent (SNP) | VAF 181/468 reads (39%) | called by muse, mutect2, varscan2
- KRT40 | c.660C>T p.L220= | Silent (SNP) | VAF 75/366 reads (20%) | catalogued as rs768330592, COSV100898828; called by muse, mutect2, varscan2
- KRT72 | c.408C>T p.F136= | Silent (SNP) | VAF 74/230 reads (32%) | catalogued as rs1189472937, COSV53373663; called by muse, mutect2, varscan2
- KRT76 | c.459G>A p.G153= | Silent (SNP) | VAF 82/469 reads (17%) | catalogued as COSV60120056; called by muse, mutect2, varscan2
- LAMA5 | c.5688G>A p.Q1896= | Silent (SNP) | VAF 89/441 reads (20%) | called by muse, mutect2, varscan2
- LAMA5 | c.3165C>T p.F1055= | Silent (SNP) | VAF 183/445 reads (41%) | catalogued as rs752996764, COSV53360572; called by muse, mutect2, varscan2
- LEPROT | c.216C>T p.F72= | Silent (SNP) | VAF 146/445 reads (33%) | called by muse, mutect2, varscan2
- LRP4 | c.4425C>T p.A1475= | Silent (SNP) | VAF 43/229 reads (19%) | called by muse, mutect2, varscan2
- LUM | c.615C>T p.V205= | Silent (SNP) | VAF 76/441 reads (17%) | catalogued as rs760543022, COSV57127681; called by muse, mutect2, varscan2
- MATR3 | c.318C>T p.D106= | Silent (SNP) | VAF 69/386 reads (18%) | catalogued as rs778392830; called by muse, mutect2, varscan2
- MKLN1 | c.1047C>T p.S349= | Silent (SNP) | VAF 150/407 reads (37%) | called by muse, mutect2, varscan2
- MRPS35 | c.474A>C p.S158= | Silent (SNP) | VAF 76/393 reads (19%) | called by muse, mutect2, varscan2
- MUC16 | c.39861G>A p.R13287= | Silent (SNP) | VAF 77/257 reads (30%) | catalogued as rs1348837044; called by muse, mutect2, varscan2
- MUC5B | c.11949T>C p.P3983= | Silent (SNP) | VAF 61/400 reads (15%) | catalogued as rs1298164175; called by muse, mutect2, varscan2
- MUC6 | c.3660C>T p.V1220= | Silent (SNP) | VAF 72/335 reads (21%) | called by muse, mutect2, varscan2
- NAT1 | c.162C>T p.A54= | Silent (SNP) | VAF 53/258 reads (21%) | called by muse, mutect2, varscan2
- NEFM | c.1872G>A p.E624= | Silent (SNP) | VAF 104/471 reads (22%) | catalogued as COSV55330108; called by muse, mutect2, varscan2
- NF1 | c.4437C>T p.F1479= (on ENST00000358273 / NM_001042492.3; = p.F1458= on NM_000267.3) | Silent (SNP) | VAF 35/149 reads (23%) | catalogued as COSV100646532; called by muse, mutect2, varscan2
- NKRF | c.42G>A p.G14= | Silent (SNP) | VAF 61/318 reads (19%) | called by muse, mutect2, varscan2
- NLRP1 | c.549G>A p.L183= | Silent (SNP) | VAF 122/460 reads (27%) | catalogued as rs1277527055; called by muse, mutect2, varscan2
- NRAS | c.180A>T p.G60= | Silent (SNP) | VAF 147/372 reads (40%) | catalogued as COSV54752785, COSV99795904; called by muse, mutect2, varscan2
- NRXN3 | c.2034C>T p.T678= (on ENST00000335750 / NM_001330195.2; = p.T305= on NM_004796.6) | Silent (SNP) | VAF 48/269 reads (18%) | catalogued as rs1430990427; called by muse, mutect2, varscan2
- NUTM2B | c.2451G>A p.K817= | Silent (SNP) | VAF 79/415 reads (19%) | called by muse, mutect2, varscan2
- OR2Y1 | c.471G>A p.L157= | Silent (SNP) | VAF 159/453 reads (35%) | catalogued as COSV100322918, COSV57136614; called by muse, mutect2, varscan2
- OR5AR1 | c.639C>T p.I213= | Silent (SNP) | VAF 62/303 reads (20%) | catalogued as COSV57253320; called by muse, mutect2, varscan2
- OR5L1 | c.534C>T p.F178= | Silent (SNP) | VAF 54/224 reads (24%) | catalogued as COSV61733014; called by muse, mutect2, varscan2
- OR5M3 | c.247C>T p.L83= | Silent (SNP) | VAF 82/337 reads (24%) | catalogued as rs779508274; called by muse, mutect2, varscan2
- OR5P3 | c.717C>T p.S239= | Silent (SNP) | VAF 94/431 reads (22%) | called by muse, mutect2, varscan2
- OR7E24 | c.429C>T p.A143= | Silent (SNP) | VAF 90/272 reads (33%) | called by muse, mutect2, varscan2
- OR9G4 | c.864C>T p.L288= | Silent (SNP) | VAF 72/378 reads (19%) | catalogued as rs750642250, COSV57248629; called by muse, mutect2, varscan2
- PACS2 | c.1386C>T p.A462= | Silent (SNP) | VAF 190/443 reads (43%) | catalogued as rs1555412192; called by muse, mutect2, varscan2
- PIDD1 | c.1035C>T p.F345= | Silent (SNP) | VAF 85/410 reads (21%) | catalogued as COSV61704796, COSV61707478; called by muse, mutect2, varscan2
- PKD2L1 | c.1467C>T p.F489= | Silent (SNP) | VAF 111/444 reads (25%) | catalogued as rs200756257, COSV58399232; called by muse, mutect2, varscan2
- PLEKHG6 | c.438G>A p.R146= | Silent (SNP) | VAF 122/312 reads (39%) | catalogued as rs776396753; called by muse, mutect2, varscan2
- PLIN4 | c.3171G>A p.R1057= (on ENST00000301286; = p.R1072= on NM_001367868.2) | Silent (SNP) | VAF 167/494 reads (34%) | catalogued as COSV56692324; called by muse, mutect2, varscan2
- PNN | c.2049C>T p.S683= | Silent (SNP) | VAF 68/322 reads (21%) | catalogued as rs1473835581; called by muse, mutect2, varscan2
- POF1B | c.1671C>T p.I557= | Silent (SNP) | VAF 53/220 reads (24%) | called by muse, mutect2, varscan2
- POU5F1B | c.1050C>T p.I350= | Silent (SNP) | VAF 55/544 reads (10%) | catalogued as rs868556173; called by muse, mutect2, varscan2
- PREX2 | c.3654C>T p.I1218= | Silent (SNP) | VAF 73/546 reads (13%) | catalogued as COSV104385129; called by muse, mutect2, varscan2
- PRKDC | c.1347C>T p.Y449= | Silent (SNP) | VAF 91/700 reads (13%) | catalogued as rs1248731322; called by muse, mutect2, varscan2
- PTCHD1 | c.207C>T p.L69= | Silent (SNP) | VAF 115/431 reads (27%) | catalogued as COSV65060638, COSV65062275; called by muse, mutect2, varscan2
- RAB11FIP1 | c.579C>T p.I193= | Silent (SNP) | VAF 71/355 reads (20%) | catalogued as COSV54760135; called by muse, mutect2, varscan2
- RBP2 | c.339G>A p.G113= | Silent (SNP) | VAF 109/360 reads (30%) | called by muse, mutect2, varscan2
- RNF133 | c.579T>C p.S193= | Silent (SNP) | VAF 137/369 reads (37%) | called by muse, mutect2, varscan2
- RPTOR | c.2976C>T p.F992= | Silent (SNP) | VAF 83/343 reads (24%) | called by muse, mutect2, varscan2
- SCN7A | c.2553G>A p.K851= | Silent (SNP) | VAF 71/338 reads (21%) | called by muse, mutect2, varscan2
- SEL1L | c.1374C>T p.L458= | Silent (SNP) | VAF 117/360 reads (33%) | called by muse, mutect2, varscan2
- SIGLEC11 | c.2082G>A p.G694= | Silent (SNP) | VAF 108/223 reads (48%) | catalogued as rs1357891510; called by muse, mutect2, varscan2
- SIPA1L1 | c.3192T>C p.N1064= | Silent (SNP) | VAF 155/405 reads (38%) | called by muse, mutect2, varscan2
- SLC38A1 | c.213C>T p.T71= | Silent (SNP) | VAF 38/249 reads (15%) | catalogued as rs564372235; called by muse, mutect2, varscan2
- SLC4A5 | c.1665G>A p.E555= | Silent (SNP) | VAF 112/323 reads (35%) | called by muse, mutect2, varscan2
- SLC7A14 | c.1107C>T p.L369= | Silent (SNP) | VAF 74/271 reads (27%) | catalogued as rs773466583; called by muse, mutect2, varscan2
- SLFN14 | c.499T>C p.L167= | Silent (SNP) | VAF 83/357 reads (23%) | catalogued as rs1013491979; called by muse, mutect2, varscan2
- SLITRK1 | c.972G>A p.A324= | Silent (SNP) | VAF 124/465 reads (27%) | catalogued as rs1467266519, COSV65674393, COSV65676911; called by muse, mutect2, varscan2
- SMYD2 | c.1218G>A p.K406= | Silent (SNP) | VAF 40/233 reads (17%) | called by muse, mutect2, varscan2
- SORCS3 | c.2808C>T p.V936= | Silent (SNP) | VAF 77/364 reads (21%) | catalogued as rs12252190; called by muse, mutect2, varscan2
- SPDEF | c.868C>T p.L290= | Silent (SNP) | VAF 61/269 reads (23%) | called by muse, mutect2, varscan2
- SPEM1 | c.528C>T p.P176= | Silent (SNP) | VAF 70/373 reads (19%) | catalogued as COSV100080963; called by muse, mutect2, varscan2
- SPINT1 | c.1020C>T p.F340= (on ENST00000344051 / NM_181642.3; = p.F324= on NM_003710.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 85/261 reads (33%) | called by muse, mutect2, varscan2
- SPTB | c.651C>T p.P217= | Silent (SNP) | VAF 76/224 reads (34%) | catalogued as rs774946538; called by muse, mutect2, varscan2
- SPTBN1 | c.198C>T p.S66= | Silent (SNP) | VAF 81/399 reads (20%) | called by muse, mutect2, varscan2
- SRPX2 | c.384C>T p.I128= | Silent (SNP) | VAF 74/360 reads (21%) | called by muse, mutect2, varscan2
- ST6GAL2 | c.456C>T p.S152= | Silent (SNP) | VAF 185/478 reads (39%) | catalogued as rs780773564, COSV64529274; called by muse, mutect2, varscan2
- STAB2 | c.5130C>T p.I1710= | Silent (SNP) | VAF 94/326 reads (29%) | called by muse, mutect2, varscan2
- SUCLG1 | c.852C>T p.S284= | Silent (SNP) | VAF 45/300 reads (15%) | called by muse, mutect2, varscan2
- SYNDIG1L | c.351C>T p.I117= | Silent (SNP) | VAF 86/407 reads (21%) | called by muse, mutect2, varscan2
- SYNGAP1 | c.3636C>T p.S1212= | Silent (SNP) | VAF 104/451 reads (23%) | catalogued as rs1436118903; called by muse, mutect2, varscan2
- TCL1B | c.222C>T p.L74= | Silent (SNP) | VAF 159/453 reads (35%) | catalogued as rs778256031; called by muse, mutect2, varscan2
- TGFBI | c.1072C>T p.L358= | Silent (SNP) | VAF 113/359 reads (31%) | called by muse, mutect2, varscan2
- TIMELESS | c.669C>T p.S223= | Silent (SNP) | VAF 122/304 reads (40%) | called by muse, mutect2, varscan2
- TMPRSS6 | c.822G>A p.K274= | Silent (SNP) | VAF 53/279 reads (19%) | called by muse, mutect2, varscan2
- TRIM24 | c.1665C>T p.P555= (on ENST00000343526 / NM_015905.3; = p.P521= on NM_003852.4) | Silent (SNP) | VAF 64/385 reads (17%) | catalogued as rs557873315; called by muse, mutect2, varscan2
- TTC29 | c.189C>T p.S63= | Silent (SNP) | VAF 73/229 reads (32%) | called by muse, mutect2, varscan2
- TTN | c.20781G>A p.G6927= (on ENST00000591111; = p.G6000= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 75/365 reads (21%) | catalogued as COSV59902811; called by muse, mutect2, varscan2
- VAV1 | c.2289C>T p.F763= | Silent (SNP) | VAF 81/199 reads (41%) | catalogued as rs773696752; called by muse, mutect2, varscan2
- VIM | c.453G>A p.E151= | Silent (SNP) | VAF 66/362 reads (18%) | called by muse, varscan2
- VWA8 | c.1614C>T p.L538= | Silent (SNP) | VAF 61/235 reads (26%) | catalogued as COSV99864839; called by muse, mutect2, varscan2
- WNK1 | c.87C>T p.S29= | Silent (SNP) | VAF 88/529 reads (17%) | called by muse, mutect2, varscan2
- XKR6 | c.984G>A p.L328= | Silent (SNP) | VAF 48/211 reads (23%) | called by muse, mutect2, varscan2
- ZNF354B | c.1059C>T p.S353= | Silent (SNP) | VAF 126/377 reads (33%) | called by muse, mutect2, varscan2
- ZNF41 | c.1446C>T p.L482= | Silent (SNP) | VAF 45/272 reads (17%) | catalogued as rs762030062; called by muse, mutect2, varscan2
- ZNF554 | c.87G>A p.E29= | Silent (SNP) | VAF 95/319 reads (30%) | called by muse, mutect2, varscan2
- ZSWIM6 | c.2277C>T p.I759= | Silent (SNP) | VAF 31/241 reads (13%) | catalogued as rs751233309, COSV53176205; called by muse, mutect2, varscan2
- AGR2 | c.478+26T>C | Intron (SNP) | VAF 157/427 reads (37%) | called by muse, mutect2, varscan2
- AL031315.1 | c.686-2236C>T | Intron (SNP) | VAF 25/116 reads (22%) | catalogued as rs1242142206; called by muse, mutect2, varscan2
- AL353804.4 | chrX:73823199 C>T | 5'Flank (SNP) | VAF 64/255 reads (25%) | called by muse, mutect2, varscan2
- CCDC33 | c.1938+462G>A | Intron (SNP) | VAF 56/264 reads (21%) | called by muse, mutect2, varscan2
- COLCA2 | c.-285+108G>A | Intron (SNP) | VAF 76/361 reads (21%) | called by muse, mutect2, varscan2
- IGHG1 | chr14:105737786 C>T | 3'Flank (SNP) | VAF 114/302 reads (38%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1394-5425G>A | Intron (SNP) | VAF 64/241 reads (27%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1394-5424G>A | Intron (SNP) | VAF 62/240 reads (26%) | called by muse, mutect2, varscan2
- LINC02185 | n.99G>A | RNA (SNP) | VAF 159/407 reads (39%) | called by muse, mutect2, varscan2
- MC1R | c.*550G>A | 3'UTR (SNP) | VAF 53/254 reads (21%) | catalogued as rs1280379165; called by muse, mutect2, varscan2
- MEGF11 | c.2711-2961G>A | Intron (SNP) | VAF 54/339 reads (16%) | called by muse, mutect2, varscan2
- OR2T2 | chr1:248441457 C>T | 5'Flank (SNP) | VAF 44/376 reads (12%) | called by muse, mutect2, varscan2
- PTPRT | c.*6104G>A | 3'UTR (SNP) | VAF 104/317 reads (33%) | called by muse, mutect2, varscan2
- RBFOX1 | c.1071+430C>T | Intron (SNP) | VAF 52/352 reads (15%) | called by muse, varscan2
- SCAMP5 | c.294-68G>T | Intron (SNP) | VAF 86/463 reads (19%) | called by muse, mutect2, varscan2
- SORBS1 | c.2128+658C>T | Intron (SNP) | VAF 92/348 reads (26%) | catalogued as rs1175477996; called by muse, mutect2, varscan2
- WDR49 | c.-65-22587C>T | Intron (SNP) | VAF 107/347 reads (31%) | called by muse, mutect2, varscan2
- Y_RNA | chr16:11316781 G>A | 3'Flank (SNP) | VAF 97/267 reads (36%) | catalogued as rs900746509; called by muse, mutect2, varscan2
